Somatic mutation profile of tumor specimen HCM-BROD-0644-C25-06B (aliquot HCM-BROD-0644-C25-06B-01D-A83U-36) from HCMI case HCM-BROD-0644-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.7 years (25,096 days).
Specimen HCM-BROD-0644-C25-06B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4574c82a-da39-4243-bf3f-823ce3e7c217.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0644-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0644-C25-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75899e55-fc3e-4afd-ab4d-f2b2b7a45cdb

The open-access MAF lists 92 somatic variants for this specimen: 68 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 23, Nonsense Mutation 6, Frame Shift Ins 3, Frame Shift Del 2, In Frame Del 2, 5'Flank 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.389T>A p.L130Q | Missense Mutation (SNP) | VAF 715/1463 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV58685390, COSV58696112, COSV58702833, COSV58725016; called by muse, mutect2, varscan2
- CHD3 | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 229/398 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1567856331; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 187/937 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 334/762 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.96+1G>T p.X32_splice | Splice Site (SNP) | VAF 180/351 reads (51%) | hotspot (GDC flag); catalogued as rs1131691003, CS167193, COSV52662718, COSV52757202, COSV53162510; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ACTN3 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 220/563 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV72207521; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 103/624 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs148746108; called by muse, mutect2, varscan2
- ARID1B | c.6430G>T p.G2144* | Nonsense Mutation (SNP) | VAF 224/808 reads (28%) | catalogued as rs1161111557; called by muse, mutect2, varscan2
- ASTN1 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 161/633 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763625810, COSV56063069, COSV99922679; called by muse, mutect2, varscan2
- BRSK1 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 142/543 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs752984665, COSV58668321, COSV58669350; called by muse, mutect2, varscan2
- CDCP1 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 160/616 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as rs199848700; called by muse, mutect2, varscan2
- CTNNA2 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 125/751 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as rs141412774, COSV63578466; called by muse, mutect2, varscan2
- FAM160A1 | c.2722_2725del p.L908Ifs*7 | Frame Shift Del (DEL) | VAF 91/392 reads (23%) | catalogued as rs752320854; called by mutect2, pindel, varscan2
- FGA | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 335/663 reads (51%) | catalogued as COSV57400687; called by muse, mutect2, varscan2
- HERC2 | c.4496G>A p.G1499D | Missense Mutation (SNP) | VAF 18/641 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs763287026, COSV99870323; called by muse, mutect2
- IGHE | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 284/794 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.03); catalogued as rs781850078; called by muse, varscan2
- MERTK | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 89/482 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773270603; called by muse, mutect2, varscan2
- MINDY4B | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 128/617 reads (21%) | catalogued as rs759419116; called by muse, mutect2, varscan2
- MPDZ | c.827C>A p.A276E | Missense Mutation (SNP) | VAF 135/583 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV59942337; called by muse, mutect2, varscan2
- NOX4 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 99/662 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1358349700; called by muse, mutect2, varscan2
- OR10G6 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 136/610 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs771526853; called by muse, mutect2, varscan2
- OR5H15 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 186/599 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV62949354; called by muse, mutect2, varscan2
- PLSCR5 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 348/901 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs559124176; called by muse, varscan2
- PRG4 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 76/1267 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs376380563, COSV63354851; called by muse, mutect2
- PRKAR2A | c.1154A>G p.Y385C | Missense Mutation (SNP) | VAF 114/486 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769798310, COSV55553115; called by muse, mutect2, varscan2
- ROCK1 | c.362dup p.W122Lfs*25 | Frame Shift Ins (INS) | VAF 96/1046 reads (9%) | catalogued as rs35810558; called by mutect2, pindel
- SASH1 | c.3472C>T p.R1158C | Missense Mutation (SNP) | VAF 179/378 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752157549, COSV66558671, COSV66564030; called by muse, mutect2, varscan2
- SDK1 | c.5743G>A p.A1915T | Missense Mutation (SNP) | VAF 213/407 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs754648325; called by muse, mutect2, varscan2
- SFMBT2 | c.2290C>T p.R764W | Missense Mutation (SNP) | VAF 449/1299 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs767296309, COSV100738611; called by muse, mutect2, varscan2
- SH3TC1 | c.3237C>G p.I1079M | Missense Mutation (SNP) | VAF 218/428 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs752719231; called by muse, mutect2, varscan2
- SKOR2 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 193/799 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101247438; called by muse, mutect2, varscan2
- SLC9A5 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 341/760 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762466239, COSV55361960; called by muse, varscan2
- SPOUT1 | c.196_198del p.K66del | In Frame Del (DEL) | VAF 98/399 reads (25%) | catalogued as rs1372380049; called by mutect2, pindel, varscan2
- SRFBP1 | c.1274T>A p.I425N | Missense Mutation (SNP) | VAF 112/396 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs745456471, COSV59583127; called by muse, mutect2, varscan2
- SYDE2 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 215/893 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as rs766453212; called by muse, mutect2, varscan2
- TBX19 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 140/574 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs772489505, COSV63197104; called by muse, mutect2, varscan2
- TRHDE | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 214/1200 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs1268997017, COSV53838461; called by muse, mutect2, varscan2
- WDR97 | c.4123G>A p.A1375T | Missense Mutation (SNP) | VAF 235/666 reads (35%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.089); catalogued as rs372718448; called by muse, mutect2, varscan2
- ZBBX | c.1631A>G p.E544G | Missense Mutation (SNP) | VAF 64/1010 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs747876325; called by muse, mutect2
- ZNF513 | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 166/844 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52009673; called by muse, mutect2, varscan2
- ZNF98 | c.305dup p.N102Kfs*12 | Frame Shift Ins (INS) | VAF 50/222 reads (23%) | catalogued as rs757764317; called by mutect2, varscan2
- AL772284.1 | c.629A>C p.E210A | Missense Mutation (SNP) | VAF 86/731 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ALDH1L2 | c.1969C>T p.R657C | Missense Mutation (SNP) | VAF 38/620 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2
- CD46 | c.1142A>G p.D381G | Missense Mutation (SNP) | VAF 93/442 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN6 | c.1853G>A p.W618* | Nonsense Mutation (SNP) | VAF 149/662 reads (23%) | called by muse, mutect2, varscan2
- DPYSL5 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 162/714 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- GRAMD4 | c.807C>G p.A269= | Splice Region (SNP) | VAF 170/509 reads (33%) | called by muse, mutect2, varscan2
- IDH3A | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 103/596 reads (17%) | called by muse, mutect2, varscan2
- KCNH1 | c.1268C>T p.A423V (on ENST00000271751 / NM_172362.3; = p.A396V on NM_002238.4) | Missense Mutation (SNP) | VAF 192/759 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- KCP | c.2467C>T p.P823S (on ENST00000620378; = p.P883S on NM_001366122.1) | Missense Mutation (SNP) | VAF 292/451 reads (65%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCTD20 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 349/623 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KREMEN2 | c.547_548dup p.R184Dfs*170 | Frame Shift Ins (INS) | VAF 330/1021 reads (32%) | called by mutect2, pindel, varscan2
- LRP1B | c.8033A>G p.N2678S | Missense Mutation (SNP) | VAF 200/446 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- MEGF8 | c.5950G>C p.E1984Q (on ENST00000251268 / NM_001271938.2; = p.E1917Q on NM_001410.3) | Missense Mutation (SNP) | VAF 379/985 reads (38%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PARD6G | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 395/1069 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDZRN4 | c.1117C>A p.P373T (on ENST00000402685 / NM_001164595.2; = p.P115T on NM_013377.4) | Missense Mutation (SNP) | VAF 237/445 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- POLD2 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 188/555 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF43 | c.314_316del p.S105del | In Frame Del (DEL) | VAF 179/346 reads (52%) | called by mutect2, pindel, varscan2
- S1PR5 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 392/849 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SETD2 | c.760del p.T254Lfs*10 | Frame Shift Del (DEL) | VAF 115/558 reads (21%) | called by mutect2, pindel, varscan2
- SLC4A1 | c.558G>T p.Q186H | Missense Mutation (SNP) | VAF 361/706 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK2 | c.132C>G p.I44M | Missense Mutation (SNP) | VAF 33/788 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- STYXL2 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 106/431 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAS2R13 | c.401T>A p.L134Q | Missense Mutation (SNP) | VAF 77/732 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- TRIM49 | c.155G>T p.C52F | Missense Mutation (SNP) | VAF 196/1189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TXN2 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 145/788 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZDHHC1 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 410/1442 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- ZNF554 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 211/414 reads (51%) | called by muse, mutect2, varscan2
- ACTN3 | c.1926C>T p.N642= | Silent (SNP) | VAF 315/832 reads (38%) | catalogued as rs368786615; called by muse, mutect2, varscan2
- CADPS | c.3600C>T p.D1200= | Silent (SNP) | VAF 125/632 reads (20%) | catalogued as rs376866233, COSV51891256; called by muse, mutect2, varscan2
- CCT8L2 | c.444C>G p.P148= | Silent (SNP) | VAF 161/674 reads (24%) | catalogued as COSV100743038; called by muse, mutect2, varscan2
- CNTN3 | c.987A>C p.I329= | Silent (SNP) | VAF 38/722 reads (5%) | called by muse, mutect2
- CYP3A7 | c.657C>T p.F219= | Silent (SNP) | VAF 71/491 reads (14%) | catalogued as rs375990155; called by muse, mutect2, varscan2
- DSP | c.480A>C p.R160= | Silent (SNP) | VAF 37/622 reads (6%) | called by muse, mutect2
- FYB2 | c.1275C>A p.V425= | Silent (SNP) | VAF 152/584 reads (26%) | called by muse, mutect2, varscan2
- GPANK1 | c.693C>T p.R231= | Silent (SNP) | VAF 637/1834 reads (35%) | called by muse, mutect2, varscan2
- HAS3 | c.246G>A p.P82= | Silent (SNP) | VAF 324/1406 reads (23%) | catalogued as rs145360778; called by muse, mutect2, varscan2
- IGHV4-28 | c.330G>A p.T110= | Silent (SNP) | VAF 198/596 reads (33%) | catalogued as rs781975086; called by muse, varscan2
- IL12RB2 | c.2298G>A p.L766= | Silent (SNP) | VAF 149/556 reads (27%) | called by muse, mutect2, varscan2
- INSYN1 | c.123C>T p.R41= | Silent (SNP) | VAF 160/643 reads (25%) | catalogued as rs372544619; called by muse, mutect2, varscan2
- KRTAP19-1 | c.252C>T p.Y84= | Silent (SNP) | VAF 105/433 reads (24%) | catalogued as rs1196043751, COSV66861156; called by muse, mutect2, varscan2
- MIS18A | c.576T>C p.L192= | Silent (SNP) | VAF 109/442 reads (25%) | catalogued as COSV51588800; called by muse, mutect2, varscan2
- NRF1 | c.1287C>T p.I429= | Silent (SNP) | VAF 169/303 reads (56%) | catalogued as rs756500940; called by muse, mutect2, varscan2
- P2RY1 | c.69G>A p.S23= | Silent (SNP) | VAF 245/1150 reads (21%) | catalogued as COSV100521684; called by muse, mutect2, varscan2
- PRELP | c.627C>T p.D209= | Silent (SNP) | VAF 155/606 reads (26%) | catalogued as rs765943721, COSV58115353; called by muse, mutect2, varscan2
- PRR14 | c.1035C>T p.C345= | Silent (SNP) | VAF 351/794 reads (44%) | catalogued as COSV54911690; called by muse, mutect2, varscan2
- SLC50A1 | c.210C>A p.I70= | Silent (SNP) | VAF 46/704 reads (7%) | called by muse, mutect2
- TTN | c.28047T>C p.N9349= (on ENST00000591111; = p.N8422= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 285/736 reads (39%) | called by muse, mutect2, varscan2
- UBR1 | c.1458A>G p.K486= | Silent (SNP) | VAF 225/521 reads (43%) | called by muse, mutect2, varscan2
- UTP14C | c.456G>A p.Q152= | Silent (SNP) | VAF 56/710 reads (8%) | called by muse, mutect2
- ZNF536 | c.45G>A p.P15= | Silent (SNP) | VAF 144/863 reads (17%) | catalogued as COSV62834081; called by muse, mutect2, varscan2
- GLRX2 | chr1:193105516 del CCTCCTCGCAGCTGAGCGCGTCCT | 5'Flank (DEL) | VAF 70/451 reads (16%) | called by mutect2, pindel, varscan2
